Somatic mutation profile of tumor specimen TCGA-2J-AABO-01A (aliquot TCGA-2J-AABO-01A-21D-A40W-08) from TCGA case TCGA-2J-AABO, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 43.4 years (15,869 days).
Specimen TCGA-2J-AABO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 331b1a0a-bd92-4755-a5b8-d65ea51ea96e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABO-10A (Blood Derived Normal), aliquot TCGA-2J-AABO-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/625f46f2-90a7-42a4-bff5-8ef4c55136c2

The open-access MAF lists 67 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 11, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 78/264 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121918572, CM090373, COSV55024503, COSV55025002; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCG4 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 103/456 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201390504; called by muse, mutect2, varscan2
- ADARB2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs368485422; called by muse, varscan2
- ADGRF3 | c.2431G>A p.A811T (on ENST00000311519 / NM_001145168.1; = p.A612T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.427); catalogued as rs1271479563, COSV100274884; called by muse, mutect2
- ANK2 | c.5351G>A p.R1784Q | Missense Mutation (SNP) | VAF 96/823 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.86); catalogued as rs777085522, COSV100000542; called by muse, mutect2, varscan2
- APOL5 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99968353; called by muse, mutect2
- CBL | c.667G>C p.A223P | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99875864; called by muse, mutect2, varscan2
- CDH8 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 52/662 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs369877864; called by muse, mutect2
- CSNK1G3 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 46/451 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100631401; called by muse, mutect2, varscan2
- DACT1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60019815; called by muse, mutect2
- DGKH | c.2003C>A p.A668D | Missense Mutation (SNP) | VAF 43/550 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99818507; called by muse, mutect2
- EGF | c.1037C>G p.A346G | Missense Mutation (SNP) | VAF 73/368 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as rs765930486, COSV99490661; called by muse, mutect2, varscan2
- EP300 | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 44/849 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1331329852, COSV99607910; called by muse, mutect2
- EPHA4 | c.1923A>C p.K641N | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99916058; called by muse, mutect2
- FAM107A | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 31/365 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs771660928, COSV62981036; called by muse, mutect2
- FAT3 | c.11963C>T p.S3988L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs780289899, COSV53107917; called by muse, mutect2, varscan2
- FCGR2B | c.645A>G p.Q215= | Splice Region (SNP) | VAF 29/203 reads (14%) | catalogued as COSV99374945; called by muse, mutect2, varscan2
- FSTL4 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99531872; called by muse, mutect2
- GPATCH8 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs199963233, COSV59199586; called by muse, mutect2
- IL21 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 43/452 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs763638879, COSV52646033; called by muse, mutect2
- IRF7 | c.910G>A p.V304M (on ENST00000397566; = p.V291M on NM_001572.5) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1226109716, COSV99199723; ClinVar: uncertain significance; called by muse, mutect2
- KCNH5 | c.2837G>A p.S946N | Missense Mutation (SNP) | VAF 102/1222 reads (8%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs967009755, COSV100525874; called by muse, mutect2
- KRT83 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1194656235, COSV53340254; called by muse, mutect2
- LCT | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 60/720 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777321408, COSV51545956; called by muse, mutect2
- LIN54 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 58/472 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100464375; called by muse, mutect2, varscan2
- MAP7D3 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs761764817, COSV100286249; called by muse, mutect2, varscan2
- NOS3 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757144684, COSV99871381; called by muse, mutect2, varscan2
- OLFM1 | c.1120G>A p.A374T (on ENST00000371793 / NM_001282611.2; = p.A356T on NM_014279.5) | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1039025372, COSV99423564; called by muse, mutect2, varscan2
- OR5M1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs553800236, COSV101591544; called by muse, mutect2, varscan2
- OR6C6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs757658611, COSV64456046; called by muse, mutect2
- PCDH11X | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as rs868409683, COSV100008489, COSV53454550; called by muse, mutect2, varscan2
- PLAAT5 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs80217781, COSV100080401; called by muse, mutect2
- POLR2B | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV100107939; called by muse, mutect2, varscan2
- PUSL1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100028130; called by muse, mutect2, varscan2
- QPCT | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1188776608, COSV100621548; called by muse, mutect2
- RAX2 | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100349611; called by muse, mutect2
- RIMS4 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 105/457 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1277817424, COSV65719391; called by muse, mutect2, varscan2
- SAFB | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV99412614; called by muse, mutect2
- SEMA4G | c.2074G>A p.A692T (on ENST00000370250; = p.A697T on NM_017893.3) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99272142; called by muse, mutect2, varscan2
- SIGLEC1 | c.3400A>G p.I1134V | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs779166120, COSV99163599; called by muse, mutect2
- SLC8A2 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52641837; called by muse, mutect2
- SYCP1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 66/836 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447626669, COSV65698038; called by muse, mutect2
- TASOR | c.3232A>C p.S1078R (on ENST00000355628 / NM_001365636.2; = p.S702R on NM_015224.3) | Missense Mutation (SNP) | VAF 88/624 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100843430, COSV62928229; called by muse, mutect2, varscan2
- TBC1D9 | c.3584G>T p.G1195V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV101464293; called by muse, mutect2
- TINF2 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV99945354; called by muse, mutect2, varscan2
- TLR8 | c.2705G>A p.R902H (on ENST00000218032 / NM_138636.5; = p.R920H on NM_016610.4) | Missense Mutation (SNP) | VAF 71/398 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99486893; called by muse, mutect2, varscan2
- TMEM87A | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 76/1146 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs1311560827, COSV100529052; called by muse, mutect2
- TNKS1BP1 | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs1461490018, COSV100835887; called by muse, mutect2
- TRIM33 | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 115/1153 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV100635147; called by muse, mutect2, varscan2
- USP10 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as rs111316824; called by muse, mutect2
- ZNF496 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 10/301 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV54180998; called by muse, mutect2
- TAF4 | c.1586_1589dup p.Q531Gfs*68 | Frame Shift Ins (INS) | VAF 78/513 reads (15%) | called by mutect2, pindel, varscan2
- ZNF835 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABCC10 | c.2037C>T p.T679= (on ENST00000372530 / NM_001198934.2; = p.T651= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/376 reads (10%) | catalogued as COSV99766945; called by muse, mutect2, varscan2
- CBLB | c.1002G>A p.G334= | Silent (SNP) | VAF 47/950 reads (5%) | catalogued as COSV99913005; called by muse, mutect2
- DSCAM | c.4827G>T p.L1609= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV101259585; called by muse, mutect2
- KCND3 | c.345C>T p.D115= | Silent (SNP) | VAF 33/346 reads (10%) | catalogued as rs1365809811, COSV56176050; called by muse, mutect2
- MAL | c.345C>T p.D115= | Silent (SNP) | VAF 101/539 reads (19%) | catalogued as rs779106964, COSV100015682; called by muse, mutect2, varscan2
- MAP3K14 | c.2070G>A p.P690= | Silent (SNP) | VAF 51/766 reads (7%) | catalogued as rs748652165, COSV100766414; called by muse, mutect2
- MCTP1 | c.2580C>T p.D860= | Silent (SNP) | VAF 90/405 reads (22%) | catalogued as rs764234404, COSV56527774, COSV56531607; called by muse, mutect2, varscan2
- PLIN4 | c.1974C>T p.T658= (on ENST00000301286; = p.T673= on NM_001367868.2) | Silent (SNP) | VAF 68/639 reads (11%) | catalogued as rs539563816, COSV100012950; called by muse, mutect2, varscan2
- TMEM248 | c.396C>T p.N132= | Silent (SNP) | VAF 34/642 reads (5%) | catalogued as rs751113175, COSV100447277; called by muse, mutect2
- ZNF256 | c.198G>A p.Q66= | Silent (SNP) | VAF 170/654 reads (26%) | catalogued as COSV99990716; called by muse, mutect2, varscan2
- ZNF646 | c.3534G>A p.K1178= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs1379160757, COSV99762121; called by muse, mutect2
- ZNF658B | n.949G>T | RNA (SNP) | VAF 86/1112 reads (8%) | called by muse, mutect2
